Gene-level copy-number profile of tumor specimen TCGA-55-7913-01B from TCGA case TCGA-55-7913, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.1 years (22,326 days).
Specimen TCGA-55-7913-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6ecf5085-d31a-469c-ac24-19a423a5262e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7913-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34cce703-d61a-486a-8664-b7089a7c40d3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,039; copy number 2: 19,311; copy number 3: 25,930; copy number 4: 3,213; copy number 5: 6,808; copy number 6: 1,689; copy number 7: 1,658; copy number 10: 39; copy number 11: 15; copy number 14: 46; copy number 16: 20; copy number 24: 19; copy number 25: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7913-01B-11D-2237-01): tumor purity 0.35, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,826 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–175,204,849, 1,130 genes, copy number 7 (broad region; genes not listed).
- chr1:230,592,660–248,919,946, 428 genes, copy number 7 (broad region; genes not listed).
- chr6:34,018,643–34,697,470, 19 genes, copy number 24 (within-gene range 3–24): GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2.
- chr6:51,410,081–51,623,428, 4 genes, copy number 7: AL158050.1, AL365219.1, AL445529.1, AL355997.1.
- chr6:62,611,153–62,611,327, 1 gene, copy number 16: AL355375.2.
- chr6:63,719,980–65,707,226, 1 gene, copy number 7 (within-gene range 5–22): EYS.
- chr6:64,377,795–64,733,837, 3 genes, copy number 7: AL357375.1, HNRNPDP2, AL355357.1.
- chr14:34,515,938–35,513,089, 39 genes, copy number 10 (within-gene range 5–10): EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6.
- chr14:38,605,255–40,905,513, 26 genes, copy number 7: AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1.
- chr19:27,638,483–32,244,083, 87 genes, copy number 11–25 (broad region; genes not listed).
- chr19:34,994,784–35,285,143, 22 genes, copy number 14: GRAMD1A, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP.
- chr20:87,250–2,177,038, 66 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
